Somatic mutation profile of tumor specimen 0DOV96 from CCDI case PBCCME, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.4 years (1,249 days).
Specimen 0DOV96: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dca4fc7d-a54a-4c21-b0f6-1edff3a7f80d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOV8J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac9fd787-c662-4932-91f4-2870c77a684d

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAP2 | c.1739C>T p.S580L | Missense Mutation (SNP) | VAF 54/354 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs760700898, COSV58283536; called by muse, mutect2, varscan2
- PRDM16 | c.492G>A p.G164= | Silent (SNP) | VAF 194/409 reads (47%) | called by muse, mutect2, varscan2
- GGT1 | c.1021-42del | Intron (DEL) | VAF 4/36 reads (11%) | catalogued as rs779615105; called by mutect2, pindel
